Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A20J, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A20J-01A (Primary Tumor).

ICD-0-3

Carcinoma, urothelial 8120/3

Site wall, posterior c67.4 for 4/7/11

PATIENT HISTORY:

The patient is a year-old white male.
PRE OP DIAGNOSIS: Bladder cancer.
POST OP DIAGNOSIS: Same.
PROCEDURE: Ileal conduit.

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, RIGHT ILIAC, BIOPSY-
ONE (1) BENIGN, REACTIVE LYMPH NODE FREE OF TUMOR.

Collection Date:

PART 2: URETER, DISTAL RIGHT, BIOPSY-
BENIGN URETER WITH NO CARCINOMA SEEN.

PART 3: URETER, DISTAL LEFT, BIOPSY-
BENIGN URETER WITH NO CARCINOMA SEEN.

PART 4: BLADDER AND PROSTATE, CYSTOPROSTATECTOMY-
A. INVASIVE POORLY DIFFERENTIATED TRANSITIONAL CELL CARCINOMA WITH FOCAL GLANDULAR DIFFERENTIATION, WHO - HIGH GRADE, ASH GRADE: IV/IV
B. TUMOR SIZE: 5 CM.
C. TUMOR INVADES INTO DEEP MUSCLE BUT NOT INTO PERIVESICAL TISSUE.
D. 22 MITOSES / 10 HPF
E. EXTENSIVE PERINEURAL INVASION IS SEEN.
F. NO ANGIOLYMPHATIC INVASION IS SEEN.
G. SEVENTEEN (17) BENIGN, REACTIVE LYMPH NODES FREE OF TUMOR.
H. URETHRAL, BILATERAL URETERIC, AND SOFT TISSUE RESECTION MARGINS ARE FREE OF TUMOR.
I. TNM STAGE: T2bN0MX
J. HISTOLOGIC GRADE: G3, POORLY DIFFERENTIATED.
K. NO DYSPLASIA / CARCINOMA IN SITU SEEN IN UNINVOLVED EPITHELIUM
L. CHRONIC CYSTITIS
M. PROSTATE WITH GLANDULAR HYPERPLASIA, NO TUMOR SEEN.
SEMINAL VESICLES WITH NO TUMOR SEEN.

PART 5: LYMPH NODE, RIGHT PELVIC, BIOPSY-
TWO (2) BENIGN REACTIVE LYMPH NODES FREE OF TUMOR.

PART 6: LYMPH NODE, LEFT PELVIC, BIOPSY-
A. BENIGN ADIPOSE TISSUE WITH NO CARCINOMA SEEN.
B. NO LYMPH NODE SEEN.

MICROSCOPIC:**SYNOPTIC - PRIMARY URINARY BLADDER/URETHRA TUMORS**

- A. Location: 3
1. Dome 4. Right wall 7. Ureter 10. No residual tumor
2. Anterior wall 5. Left wall 8. Urethra
3. Posterior wall 6. Trigone 9. Multicentric
- B. Procedure: 4
1. Biopsy/TURBT 3. Total cystectomy 5. Other
2. Partial cystectomy 4. Cystoprostatectomy
- C. Size (if multicentric, size of the most deeply invasive or largest tumor): 5 cm
- D. Non-invasive neoplastic lesions: N/A
1. Papilloma 4. Flat CIS
2. Inverted papilloma 5. Other
3. Papillary TCCa
- E. Invasive neoplasia: 1
1. Transitional cell carcinoma 6. Mixed urothelial carcinoma
2. Squamous carcinoma 7. Lymphoma/leukemia
3. Adenocarcinoma 8. Sarcoma
4. Sarcomatoid carcinoma 9. Metastasis/direct extension from a contiguous primary
5. Small cell/neuroendocrine carcinoma 10. Other
- F. Grade: 4 (Ash for TCCa), 3 (WHO for TCCa); NA other (non-TCCa)
- G. Non-neoplastic and other conditions: 1
1. Von Brunn's nests, cystitis cystica/glandularis, intestinal metaplasia
2. Nephrogenic metaplasia/adenoma
3. Granulomatous cystitis
4. Interstitial cystitis
5. Inflammatory pseudotumors
6. Carbuncle
7. Malakoplakia
8. Other
- H. Margins of resection: 2
1. Positive 2. Negative
- I. Angiolymphatic invasion: 2
1. Positive 2. Negative
- J. Perineural invasion: 1
1. Positive 2. Negative
- K. Mitotic activity: 22 per 10 high power fields
- L. Lymph node metastasis: 0 of 17 lymph nodes contain metastasis
- M. Prostate/seminal vesicles (if cystoprostatectomy)
M1. Involved by bladder neoplasm: 2
1. Yes 2. No
M2. Concurrent primary invasive prostatic neoplasm: 2
1. Yes 2. No
M3. High grade PIN: 2
1. Yes 2. No
- N. TNM stage: T2b N0 M X

Source: NCI Genomic Data Commons file 775e6204-b1ae-41c7-87ea-78999b9fc2d9 (TCGA-BT-A20J.74E5CF6B-F334-44D7-944E-8E59879AAE90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).